Gene-level copy-number profile of tumor specimen TCGA-J1-A4AH-01A from TCGA case TCGA-J1-A4AH, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.9 years (25,893 days).
Specimen TCGA-J1-A4AH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.267eda8d-44fc-488e-80e0-a6e22a9c54e1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-J1-A4AH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d8e2ffdd-5a91-47cd-aa7a-12c2066c77c1

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 32,509; copy number 2: 22,620; copy number 3: 3,661; copy number 4: 203; copy number 5: 86; copy number 6: 201; copy number 7: 28; copy number 8: 41; copy number 9: 175; copy number 14: 263.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-J1-A4AH-01A-31D-A24C-01): tumor purity 0.33, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:66,093,431–66,094,909, 1 gene: NUFIP1P1.
- chr15:23,912,411–24,090,821, 1 gene (within-gene range 0–1): PWRN4.
- chr15:24,162,754–24,240,192, 3 genes: PWRN2, AC087463.1, AC087463.2.
- chr15:62,196,066–63,158,021, 25 genes (within-gene range 0–2): AC126323.2, AC126323.1, AC126323.3, Metazoa_SRP, GOLGA2P11, AC126323.4, AC126323.6, AC126323.5, MIR8067, MIR6085, HMGN1P26, AC032011.1, TLN2, MGC15885, AC100839.1, MIR190A, AC103740.1, AC103740.2, AC079328.1, TPM1, TPM1-AS, AC079328.2, AC087612.1, LACTB, RPS27L.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 4,655 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,195,633–171,638,799, 382 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr2:28,683,976–31,414,742, 43 genes, copy number 6–7 (within-gene range 2–7): RNA5SP89, AC092164.1, PPP1CB, SPDYA, AC097724.1, TRMT61B, WDR43, SNORD92, SNORD53, Y_RNA, SNORD53B, TOGARAM2, Y_RNA, PCARE, AC105398.1, CLIP4, ALK, AC074096.1, RN7SL516P, AC106870.3, AC106870.2, AC106870.1, AC016907.2, AC016907.1, YPEL5, SNORA10B, H3P5, LBH, AC109642.1, LINC01936, AC073255.1, LCLAT1, AC132154.1, CAPN13, AC092569.1, AC009301.1, GALNT14, AC009305.1, CAPN14, RNA5SP90, EHD3, AL121657.1, XDH.
- chr2:56,750,300–66,200,373, 164 genes, copy number 4–9 (within-gene range 2–9) (broad region; genes not listed).
- chr2:66,904,436–67,684,077, 9 genes, copy number 6 (within-gene range 2–6): LINC01799, LINC01628, AC007403.1, LINC01828, LINC01829, AC023115.1, ETAA1, LINC02831, AC007422.1.
- chr2:69,893,956–79,123,409, 201 genes, copy number 3–4 (broad region; genes not listed).
- chr2:113,610,502–115,940,291, 28 genes, copy number 3: RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P, SLC35F5, MIR4782, AC104653.2, AC104653.1, AC110769.2, ACTR3, AC110769.3, LINC01191, AC110769.1, U3, AC010982.2, AC010982.1, SEPHS1P7, RNU2-41P, DPP10, DPP10-AS3, DPP10-AS2, AC093610.1, DPP10-AS1, RPSAP23, AC016721.1.
- chr2:121,040,610–122,887,691, 19 genes, copy number 3: Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823, AC011246.1, AC073632.1.
- chr2:131,035,092–131,093,460, 2 genes, copy number 4: SMIM39, FAM168B.
- chr2:133,391,109–133,596,399, 4 genes, copy number 5: RN7SKP154, NCKAP5-IT1, AC011243.1, RN7SKP93.
- chr2:135,510,546–142,131,016, 54 genes, copy number 6–8 (within-gene range 1–8): G3BP1P1, R3HDM1, RNU6-512P, MIR128-1, UBXN4, LCT, Y_RNA, LCT-AS1, MCM6, MANEALP1, DARS1, DARS-AS1, AC068492.1, CXCR4, HNRNPKP2, AC112255.1, UBBP1, RN7SKP141, SMC4P1, THSD7B, RNA5SP105, Y_RNA, HNMT, LINC01832, RPL15P5, YWHAEP5, IDI1P1, RNF14P1, AC114763.1, AC114763.2, SPOPL, AC092620.1, AC092620.2, LINC02631, NXPH2, RN7SKP286, YY1P2, AHCYP4, AC023468.1, AC013265.1, AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27, LRP1B, AC092156.1, MIR7157.
- chr2:141,208,082–143,055,833, 6 genes, copy number 8 (within-gene range 1–8): RPS16P3, AC078882.1, UBE2V1P14, RRN3P4, KYNU, SFXN4P1.
- chr3:89,107,621–96,619,831, 34 genes, copy number 3 (within-gene range 1–3): EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8.
- chr3:100,221,268–193,378,820, 1,540 genes, copy number 3–14 (within-gene range 2–14) (broad region; genes not listed).
- chr4:52,252,820–54,355,954, 39 genes, copy number 3–4 (within-gene range 1–4): AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283.
- chr5:14,143,342–14,532,128, 2 genes, copy number 3 (within-gene range 2–3): TRIO, AC016549.1.
- chr6:41,666,906–43,576,038, 83 genes, copy number 3 (broad region; genes not listed).
- chr8:36,987,977–38,601,200, 56 genes, copy number 3–6: AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1.
- chr8:48,818,293–68,331,689, 279 genes, copy number 3 (broad region; genes not listed).
- chr8:82,033,533–82,961,926, 1 gene, copy number 4 (within-gene range 2–5): AC060765.2.
- chr8:82,514,568–86,212,236, 53 genes, copy number 3–4: AC060765.1, AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419, AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1, REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, AC100801.2, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1.
- chr8:104,590,733–105,804,539, 1 gene, copy number 3 (within-gene range 2–3): ZFPM2.
- chr8:104,981,164–121,994,185, 147 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr11:59,107,185–60,542,721, 64 genes, copy number 3 (broad region; genes not listed).
- chr12:66,767–2,954,338, 74 genes, copy number 3 (broad region; genes not listed).
- chr17:55,264,960–59,403,303, 118 genes, copy number 3–5 (broad region; genes not listed).
- chr18:11,486,205–12,377,227, 46 genes, copy number 3 (within-gene range 2–3): LINC01255, AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, MIR7153, AP001120.1, GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3, IMPA2, AP001269.1, AP001542.3, AP001542.1, AP001542.2, AP002414.1, AP002414.4, AP002414.2, AP002414.5, AP002414.3, ANKRD62, RNU6-324P, SDHDP1, PMM2P2, AP005264.5, AP005264.3, AP005264.4, CCDC58P3, AP005264.2, PPIAP56, CIDEA, AP005264.6, AP005264.1, RNU6-170P, TUBB6, AFG3L2.
- chr18:20,946,906–22,205,229, 36 genes, copy number 3: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3.
- chr18:29,256,817–32,131,561, 47 genes, copy number 3: AC105245.1, AC074237.1, AC117569.1, AC117569.2, AC115100.1, MIR302F, AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2.
- chr18:32,176,050–32,220,404, 3 genes, copy number 3 (within-gene range 2–3): RNA5SP453, MEP1B, CLUHP6.
- chr18:36,273,574–57,029,811, 255 genes, copy number 3–5 (within-gene range 2–5) (broad region; genes not listed).
- chr18:71,000,477–77,650,973, 104 genes, copy number 3–6 (broad region; genes not listed).
- chr19:27,638,483–35,813,299, 248 genes, copy number 3 (broad region; genes not listed).
- chr20:87,250–25,452,628, 513 genes, copy number 3 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 30,271. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
